Somatic mutation profile of tumor specimen TCGA-YZ-A985-01A (aliquot TCGA-YZ-A985-01A-11D-A39W-08) from TCGA case TCGA-YZ-A985, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 41.5 years (15,164 days).
Specimen TCGA-YZ-A985-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82190ddf-9182-4ffe-93b0-f4166ebcbd03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YZ-A985-10A (Blood Derived Normal), aliquot TCGA-YZ-A985-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/685a8c20-b4da-4def-91f8-2421e874cc8d

The open-access MAF lists 440 somatic variants for this specimen: 315 protein-altering or splice-affecting, 119 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 291, Silent 119, Nonsense Mutation 17, Splice Site 3, Frame Shift Del 2, Intron 2, 3'Flank 2, Splice Region 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | catalogued as rs201391050, CM080032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP17A1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs61754278, CM960476, COSV64004824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555702147, COSV50017316; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PLCB4 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs1568763104, COSV53793606, COSV53801055; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 13/18 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ADAD2 | c.1426G>A p.E476K (on ENST00000315906 / NM_001145400.2; = p.E558K on NM_139174.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754189973, COSV51893826; called by muse, mutect2, varscan2
- ADGRA2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55103335; called by muse, mutect2
- ADIPOR1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs766587890, COSV61851334; called by muse, mutect2, varscan2
- AGAP1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV58323024; called by muse, mutect2, varscan2
- AGAP2 | c.2057G>A p.R686Q (on ENST00000547588 / NM_001122772.2; = p.R350Q on NM_014770.4) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57729592; called by muse, mutect2, varscan2
- AGRN | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1205781353; called by muse, mutect2, varscan2
- AKAP13 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs753131765; called by muse, mutect2, varscan2
- ALDH1A3 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM163655; called by muse, mutect2, varscan2
- ANGPT4 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs746445808, COSV67921665; called by muse, mutect2, varscan2
- AP3B2 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.457); catalogued as rs1362293215; called by muse, mutect2, varscan2
- AP3D1 | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as rs369318068; called by muse, mutect2, varscan2
- APOA4 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs113263292; called by muse, mutect2, varscan2
- ARHGEF10L | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750101839, COSV51430940; called by muse, mutect2, varscan2
- ARHGEF17 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs373537661; called by muse, mutect2, varscan2
- ARMCX1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.959); catalogued as rs1556027265, COSV65704919; called by muse, mutect2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2, varscan2
- ASB11 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs760467867, COSV60355288, COSV60355922; called by muse, mutect2, varscan2
- ASCC3 | c.4415G>A p.R1472Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051651433, COSV64978721; called by muse, mutect2, varscan2
- ATF7IP | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as rs1180964456; called by muse, mutect2, varscan2
- ATP1A2 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV63402254; called by muse, mutect2, varscan2
- B4GALNT2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs776879040, COSV55928297; called by muse, mutect2, varscan2
- BBOX1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764375198, COSV54192621; called by muse, mutect2, varscan2
- BEND3 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1554231348, COSV64682505; called by muse, varscan2
- BICD1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs199625504; called by muse, mutect2, varscan2
- BICRA | c.3604G>A p.V1202M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs536150980, COSV67604295; called by muse, mutect2
- BZW2 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs371407289; called by muse, mutect2
- C3orf56 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371883407; called by muse, mutect2, varscan2
- CACHD1 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs182391558, COSV51547812; called by muse, mutect2, varscan2
- CACNA1C | c.3643G>A p.V1215M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs747533547, COSV59700086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.2750C>T p.T917M (on ENST00000350061 / NM_001128840.3; = p.T937M on NM_000720.4) | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs145327253; called by muse, mutect2, varscan2
- CACNA2D1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs758561622, COSV62382055; called by muse, mutect2, varscan2
- CAMSAP1 | c.3428G>A p.R1143Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as rs749209361; called by muse, mutect2, varscan2
- CASC3 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1447750347; called by muse, mutect2, varscan2
- CBX2 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as rs61738483; called by muse, mutect2, varscan2
- CCN4 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51531488; called by muse, mutect2, varscan2
- CDC20B | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338716023; called by muse, mutect2, varscan2
- CDH18 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as rs750768779, COSV56917098; called by muse, mutect2
- CDH7 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as rs1269949009, COSV59898182; called by muse, mutect2, varscan2
- CELSR1 | c.3791C>T p.A1264V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as rs1227807619, COSV99418150; called by muse, mutect2
- CEP131 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs372370793; called by muse, mutect2, varscan2
- CFAP43 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs371285570; called by muse, mutect2, varscan2
- CFAP52 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780939657; called by muse, mutect2, varscan2
- CFP | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99901751; called by muse, mutect2, varscan2
- CHMP7 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.46); PolyPhen benign (0.201); catalogued as rs1346755630; called by muse, mutect2, varscan2
- CHRM1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV61006143; called by muse, mutect2
- CIITA | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs141095229; called by muse, mutect2, varscan2
- CLP1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs777290319, COSV57053898; called by muse, mutect2, varscan2
- CNGA2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs748063457, COSV61703945; called by muse, mutect2, varscan2
- CNTN2 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756558390; called by muse, mutect2, varscan2
- CNTNAP5 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.549); catalogued as rs375042758; called by muse, mutect2, varscan2
- COG2 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs753073596, COSV64187943; called by muse, mutect2, varscan2
- COL5A1 | c.4537G>A p.G1513S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489565447, COSV100879461; called by muse, mutect2, varscan2
- COL9A2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs767929481; called by muse, mutect2, varscan2
- COX16 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as rs761014452, COSV66303043; called by muse, mutect2, varscan2
- CPNE6 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs755460754; called by muse, varscan2
- CTTNBP2 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200782612, COSV50392485; called by muse, mutect2, varscan2
- CUEDC1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs150759994, COSV64226368; called by muse, mutect2, varscan2
- CUL7 | c.3434G>A p.R1145H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs757432567; called by muse, mutect2, varscan2
- CYTH3 | c.975+1G>A p.X325_splice (on ENST00000396741; = p.X324_splice on NM_004227.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 30/62 reads (48%) | catalogued as rs764184600, COSV60363506; called by muse, mutect2, varscan2
- DAPK1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs753510016, COSV63789576; called by muse, mutect2, varscan2
- DCAF12 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs1276644935, COSV63513894; called by muse, mutect2
- DDHD2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1201437383; called by muse, mutect2, varscan2
- DEPDC5 | c.2299C>T p.R767C (on ENST00000400246; = p.R836C on NM_014662.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs780652126, COSV56704980; called by muse, mutect2
- DGKQ | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.999); catalogued as rs756724535, COSV53277554; called by muse, mutect2, varscan2
- DGKQ | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs143203696; called by muse, mutect2, varscan2
- DHRS3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs765594786, COSV66108438; called by muse, mutect2, varscan2
- DIDO1 | c.6047C>T p.P2016L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs762357648; called by muse, mutect2, varscan2
- DLGAP3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs377551672; called by muse, mutect2
- DLX2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414617008, COSV52233002; called by muse, mutect2, varscan2
- DNAH2 | c.7285G>A p.V2429I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.304); catalogued as rs771140126, COSV66720969; called by mutect2, varscan2
- DPEP2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs768027580, COSV99263083; called by muse, mutect2, varscan2
- DSCAML1 | c.5605G>A p.E1869K (on ENST00000321322; = p.E1809K on NM_020693.4) | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394687991, COSV58391648; called by muse, mutect2, varscan2
- DSCAML1 | c.343G>A p.A115T (on ENST00000321322; = p.A55T on NM_020693.4) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs775200712, COSV100355237; called by muse, mutect2, varscan2
- DUSP11 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as rs754705080, COSV55595147, COSV99730981; called by muse, mutect2, varscan2
- EFEMP2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs573771187, COSV57259852; called by muse, mutect2, varscan2
- EFNA4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs200331554, COSV63018009; called by muse, mutect2, varscan2
- EGF | c.1189+1G>A p.X397_splice | Splice Site (SNP) | VAF 9/93 reads (10%) | catalogued as rs764061176; called by muse, mutect2, varscan2
- EIF2AK2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51794332; called by muse, mutect2, varscan2
- ELAPOR2 | c.2636C>T p.T879M (on ENST00000450689 / NM_001142749.3; = p.T712M on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs760928278, COSV51892954; called by muse, mutect2, varscan2
- ELOVL2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs202019761, COSV61156962; called by muse, mutect2, varscan2
- EPPK1 | c.2212G>A p.V738M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs746589906; called by muse, mutect2
- ERAP2 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs73150323; called by muse, mutect2, varscan2
- ERC1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs549963000; called by muse, mutect2, varscan2
- F7 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as rs374305125, CD010610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM241A | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs866555738, COSV59036448; called by muse, mutect2, varscan2
- FAT2 | c.11749G>A p.V3917M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs756607776, COSV55816219; called by mutect2, varscan2
- FBXL18 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs752384431, COSV66665273, COSV66665695; called by muse, mutect2, varscan2
- FBXO46 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs764409127, COSV100480209; called by muse, mutect2
- FGFR4 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs55879131; called by muse, mutect2, varscan2
- FKTN | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs200686690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL1 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302823411, COSV100055955; called by muse, mutect2, varscan2
- FMO2 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs187393653, COSV52950089, COSV99269261; called by muse, mutect2, varscan2
- FMO3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs751472166, COSV63008674; called by muse, mutect2, varscan2
- FNDC1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544765580, COSV51936499; called by muse, mutect2, varscan2
- FOXO3 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as rs535867091, COSV59630425; called by muse, mutect2, varscan2
- FOXP2 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs745987986, COSV63484878; called by muse, mutect2, varscan2
- FRAS1 | c.4363G>A p.A1455T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.743); catalogued as rs771270397; called by muse, varscan2
- FUT9 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765684352, COSV56142633, COSV56148853; called by muse, mutect2, varscan2
- GABRD | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1459168993, COSV66080286; called by muse, mutect2, varscan2
- GALNT2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs151140953; called by muse, mutect2, varscan2
- GDAP1L1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as rs777303313, COSV61157481; called by muse, mutect2, varscan2
- GIP | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367741847; called by muse, mutect2, varscan2
- GJA1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs367628979, COSV56999590; called by muse, mutect2, varscan2
- GLP1R | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs368940624; called by muse, mutect2, varscan2
- GPA33 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs767074475; called by muse, mutect2, varscan2
- GPR4 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as rs763872953, COSV59918250; called by muse, mutect2, varscan2
- GRHL2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as rs772933548, COSV104381766; called by muse, mutect2, varscan2
- GRHL3 | c.1226G>A p.R409H (on ENST00000350501 / NM_198174.3; = p.R414H on NM_021180.3) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1261266801; called by muse, mutect2, varscan2
- GRIK3 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.427); catalogued as rs376333303; called by muse, mutect2, varscan2
- GSR | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138721223; called by muse, mutect2, varscan2
- GTF2E2 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs763006801; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100736416, COSV100736448; called by mutect2, varscan2
- HDAC5 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99870995; called by muse, mutect2, varscan2
- HDAC5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs746035403, COSV56817977; called by muse, mutect2
- HDLBP | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV60498645; called by muse, mutect2, varscan2
- HSD11B1L | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs1214771188; called by muse, mutect2
- HSPG2 | c.7318C>T p.R2440W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1160285381, COSV65969175; called by muse, mutect2, varscan2
- HTR2B | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs180891719; called by muse, mutect2, varscan2
- HUWE1 | c.6008C>T p.T2003M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs782477771, COSV53343668; called by muse, mutect2, varscan2
- IGSF9B | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1235172280, COSV58065092; called by muse, mutect2
- IGSF9B | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750817042, COSV58066675; called by muse, mutect2, varscan2
- IL17RD | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1486656267; called by muse, mutect2, varscan2
- IL25 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs767350854, COSV59306867; called by muse, mutect2, varscan2
- IMP4 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.085); catalogued as rs11542413; called by muse, mutect2, varscan2
- IRAG1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs565811419; called by muse, varscan2
- ITGAX | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs200458998, COSV51650268; called by muse, mutect2, varscan2
- IVD | c.388G>A p.G130S (on ENST00000651168; = p.G127S on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs754570116; called by muse, mutect2, varscan2
- JCAD | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs772929418, COSV64757781; called by muse, mutect2
- KAT2A | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.076); catalogued as rs781796429, COSV56790563; called by muse, mutect2, varscan2
- KCNE3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs371666083; called by muse, mutect2, varscan2
- KIAA0586 | c.2119G>A p.D707N (on ENST00000619416 / NM_001244190.2; = p.D646N on NM_014749.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs750671663; called by muse, mutect2, varscan2
- KIAA1217 | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751142962, COSV56824384; called by muse, mutect2, varscan2
- KLHL26 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs148044384; called by muse, mutect2, varscan2
- KMT2D | c.7769C>T p.S2590L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs760007799, COSV56421757; called by muse, mutect2
- LAMA3 | c.6440G>A p.R2147Q (on ENST00000313654 / NM_198129.4; = p.R538Q on NM_000227.6) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201023601; called by muse, mutect2
- LARP1 | c.821G>A p.R274H (on ENST00000518297 / NM_033551.3; = p.R197H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs779864945; called by muse, mutect2, varscan2
- LLGL2 | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs370466207; called by muse, mutect2, varscan2
- LPCAT1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307070775, COSV52035447; called by muse, mutect2, varscan2
- LRFN1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219603059; called by muse, mutect2, varscan2
- LRFN3 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as rs760444261; called by muse, mutect2, varscan2
- LRP2 | c.12137G>A p.R4046Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as rs867978150; called by muse, mutect2, varscan2
- LRP2BP | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as rs201973995; called by muse, mutect2, varscan2
- LRRC30 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV67301708; called by muse, mutect2, varscan2
- LRRC8A | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771228754, COSV52187071; called by muse, mutect2, varscan2
- LY6G6C | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs761749993; called by muse, mutect2, varscan2
- LZTS3 | c.1927G>A p.A643T (on ENST00000329152; = p.A597T on NM_001282533.2) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.081); catalogued as rs144495581, COSV99418141; called by muse, mutect2, varscan2
- MAB21L4 | c.826G>A p.D276N (on ENST00000388934 / NM_001085437.3; = p.D108N on NM_024861.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as rs757923540; called by muse, mutect2, varscan2
- MAOB | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778570953; called by muse, mutect2, varscan2
- MAP2K3 | c.116+1G>A p.X39_splice (on ENST00000342679 / NM_145109.3; = p.X10_splice on NM_002756.4) | Splice Site (SNP) | VAF 20/110 reads (18%) | catalogued as rs368105298, COSV57575118; called by muse, mutect2, varscan2
- MAP3K19 | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749899105; called by muse, mutect2, varscan2
- MAP3K5 | c.3667G>A p.V1223M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs766760055, COSV62886601; called by muse, mutect2, varscan2
- MATK | c.1265G>A p.R422Q (on ENST00000310132 / NM_139355.3; = p.R423Q on NM_002378.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780442262; called by muse, mutect2, varscan2
- MED25 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.338); catalogued as rs1018204701, COSV57204006; called by muse, mutect2, varscan2
- MED9 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1342679748, COSV51957529; called by muse, mutect2, varscan2
- MEN1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as rs878855197, CM004415, CM045305, COSV53640570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MERTK | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765685308; called by muse, mutect2, varscan2
- MEST | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs782149861; called by muse, mutect2, varscan2
- MLC1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs757541925; called by muse, mutect2, varscan2
- MUC2 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.31); catalogued as rs750954497; called by muse, mutect2
- MUC4 | c.16156G>A p.G5386R (on ENST00000463781 / NM_018406.7; = p.G1150R on NM_004532.6) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.289); catalogued as rs769504147, COSV57778525; called by muse, mutect2, varscan2
- MYBPC2 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439007318, COSV63099333; called by muse, mutect2, varscan2
- MYCBPAP | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs1473578827, COSV60405372; called by muse, mutect2, varscan2
- MYO1F | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs201138222, COSV57796026; called by muse, mutect2, varscan2
- MYOF | c.3073C>T p.R1025* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as rs775643885; called by muse, mutect2, varscan2
- NCR3 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 36/79 reads (46%) | catalogued as rs748321504, COSV53000507, COSV99278988; called by muse, mutect2, varscan2
- NEB | c.19220G>A p.R6407Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs745615279, COSV51441238, COSV51460697; called by muse, mutect2, varscan2
- NGFR | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.139); catalogued as rs534528579, COSV50803870; called by muse, mutect2, varscan2
- NOP10 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs201604296, COSV60995433; called by muse, mutect2, varscan2
- NOS1AP | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.01); catalogued as rs760300331, COSV62639941; called by muse, mutect2, varscan2
- NSD1 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs774810620, COSV61780019; called by muse, mutect2, varscan2
- NUP210 | c.4228G>A p.D1410N | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.852); catalogued as rs769147767, COSV54406568; called by muse, mutect2, varscan2
- OBSCN | c.13843C>T p.R4615W | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs528758181; called by muse, mutect2, varscan2
- OR2A14 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV101376449, COSV101376499; called by muse, mutect2, varscan2
- OR5C1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs772591814; called by muse, mutect2, varscan2
- OXLD1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs752069209, COSV100235870; called by mutect2, varscan2
- P2RY2 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs1292801922, COSV60776120; called by muse, mutect2, varscan2
- PANK4 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs753091403, COSV65866365; called by muse, mutect2, varscan2
- PARD3 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV60757657; called by muse, mutect2, varscan2
- PCDHB7 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782528648, COSV50799178, COSV99177125; called by muse, mutect2, varscan2
- PCSK7 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1407631588, COSV100309357, COSV100309381; called by muse, mutect2
- PDE6B | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199768318, COSV55325135; called by muse, mutect2, varscan2
- PDZD2 | c.7123G>A p.G2375S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs761908408, COSV56858806; called by muse, mutect2, varscan2
- PGAM4 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782085897; called by muse, mutect2
- PHKA2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs191267737, COSV66055277; called by muse, mutect2, varscan2
- PLA2G6 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752794250, COSV100140488, COSV100140501; called by muse, mutect2, varscan2
- PLA2G6 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs755993359, COSV59268678; called by muse, mutect2, varscan2
- PLCD4 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs776903135, COSV101335818; called by muse, varscan2
- PLEC | c.13612G>A p.D4538N (on ENST00000322810 / NM_201380.4; = p.D4428N on NM_000445.5) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.435); catalogued as rs782439392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIA1 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs750191381, COSV54131213; called by muse, mutect2
- PPFIBP2 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs201945661; called by muse, mutect2, varscan2
- PPL | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs763239987; called by muse, mutect2, varscan2
- PPP6R2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775856214; called by muse, mutect2, varscan2
- PRAG1 | c.4172C>T p.A1391V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746332662; called by muse, mutect2, varscan2
- PRRC2A | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1258585778; called by muse, mutect2, varscan2
- PSD4 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201700173, COSV55525638; called by muse, mutect2, varscan2
- PSMF1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762622706; called by muse, mutect2, varscan2
- PTPN21 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100162404; called by muse, mutect2, varscan2
- PTPRU | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as rs752247574; called by muse, mutect2, varscan2
- RAC2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1443752435; called by muse, mutect2, varscan2
- RAC3 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as rs1379395211; called by muse, mutect2, varscan2
- RAD23B | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.661); catalogued as rs372514872; called by muse, mutect2, varscan2
- RADIL | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs369472639; called by muse, mutect2, varscan2
- RADIL | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200059500; called by muse, varscan2
- RBL1 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs374029496, COSV60330080; called by muse, mutect2, varscan2
- RBM22 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52271021; called by muse, mutect2, varscan2
- REC8 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.626); catalogued as rs1475840583; called by muse, mutect2, varscan2
- RERE | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs772909728; called by muse, mutect2
- RET | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); catalogued as rs759229505, COSV60704547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REXO1 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs202065048; called by muse, mutect2
- RNF43 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs759694077, COSV68459662, COSV68459732; called by muse, mutect2, varscan2
- RNPEPL1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs757698209; called by muse, varscan2
- RTL5 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.166); catalogued as rs373524278, COSV101029985, COSV65453092; called by mutect2, varscan2
- RTL5 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as COSV65454048; called by mutect2, varscan2
- RUNX1 | c.818C>T p.T273M (on ENST00000344691 / NM_001001890.3; = p.T300M on NM_001754.5) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs758682659, COSV55866372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.9679C>T p.R3227C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs747271394, COSV63695082; called by muse, mutect2, varscan2
- SBF1 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780146082, COSV62369515; called by muse, mutect2, varscan2
- SBSPON | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs757345283, COSV52078369; called by muse, mutect2, varscan2
- SCN2A | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV51840749; called by muse, mutect2, varscan2
- SEPTIN6 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764588243, COSV59715333; called by muse, mutect2, varscan2
- SERPINA3 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs373526796; called by muse, mutect2, varscan2
- SIPA1L3 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs778077624; called by mutect2, varscan2
- SLC13A1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774399049, CM142587; called by muse, mutect2, varscan2
- SLC16A2 | c.1450G>A p.G484S | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs752570148; called by muse, mutect2, varscan2
- SLC18B1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs573567211, COSV99259120; called by muse, mutect2, varscan2
- SLC22A14 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as rs760758304, COSV56196780; called by muse, mutect2, varscan2
- SLC35F3 | c.217G>A p.V73M (on ENST00000366617 / NM_001300845.1; = p.V142M on NM_173508.4) | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs530447111, COSV104426931, COSV64021032; called by muse, mutect2, varscan2
- SLC6A12 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1044859657; called by muse, mutect2, varscan2
- SLC9A3 | c.1928C>T p.T643M | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs150973602; called by muse, mutect2, varscan2
- SLCO2B1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1009964902, COSV99215093; called by muse, mutect2, varscan2
- SLITRK3 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1490316717, COSV53852040; called by muse, mutect2, varscan2
- SMPD3 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs200081668, COSV54715870; called by muse, mutect2, varscan2
- SNRNP25 | c.98T>C p.I33T (on ENST00000383018; = p.I24T on NM_024571.4) | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as rs1024654436, COSV51955144; called by muse, mutect2
- SPAG5 | c.1740G>A p.A580= | Splice Region (SNP) | VAF 24/124 reads (19%) | catalogued as rs1318352378; called by muse, mutect2, varscan2
- SPTBN4 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs748767389, COSV58943967; called by muse, mutect2, varscan2
- SRSF4 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs1447567488, COSV65694535; called by muse, mutect2, varscan2
- ST3GAL3 | c.931C>T p.R311W (on ENST00000361392 / NM_174964.4; = p.R296W on NM_006279.5) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs554609799; called by muse, mutect2, varscan2
- SUGP2 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs144507791; called by mutect2, varscan2
- SUN5 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766701001, COSV62180343; called by muse, mutect2, varscan2
- TBC1D15 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100042203; called by muse, mutect2, varscan2
- TBL2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs373074498; called by muse, mutect2, varscan2
- TCHH | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs780658407, COSV64278195; called by muse, mutect2
- THBS2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs749837715, COSV64682587; called by muse, mutect2, varscan2
- THBS3 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs373078740; called by muse, mutect2, varscan2
- TKFC | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs750037556; called by muse, mutect2, varscan2
- TLN2 | c.3413G>A p.R1138H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs750147149; called by muse, mutect2, varscan2
- TNS3 | c.3728C>T p.P1243L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs375611617; called by muse, mutect2, varscan2
- TOX3 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768449574; called by muse, mutect2, varscan2
- TRIM56 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1401771086, COSV100047644; called by muse, mutect2, varscan2
- TRIM63 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs764437396; called by muse, mutect2, varscan2
- TRIO | c.9112C>T p.R3038C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321773037; called by mutect2, varscan2
- TTC37 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs143193581; called by muse, mutect2, varscan2
- TTC8 | c.1201C>T p.R401C (on ENST00000338104 / NM_001288781.1; = p.R385C on NM_144596.4) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772733868; called by muse, mutect2, varscan2
- TTN | c.74762G>A p.R24921Q (on ENST00000591111; = p.R17497Q on NM_003319.4) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | PolyPhen probably damaging (0.996); catalogued as rs538960023; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.8624C>T p.A2875V (on ENST00000591111; = p.A2829V on NM_003319.4) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | PolyPhen probably damaging (0.997); catalogued as rs1335787072; called by muse, mutect2, varscan2
- TXN2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as rs780339679, COSV53397339; called by muse, mutect2, varscan2
- UBE2J2 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs146586696; called by muse, mutect2, varscan2
- UNC5CL | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs773255844, COSV55112234, COSV99770864; called by muse, mutect2, varscan2
- UTRN | c.4588G>A p.A1530T | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771082025, COSV100839462; called by muse, mutect2, varscan2
- VWA2 | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768137633, COSV53911265; called by muse, mutect2, varscan2
- WDR27 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs376971037; called by muse, mutect2, varscan2
- XAB2 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1467600531, COSV50367954; called by muse, varscan2
- XPO7 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs774932634; called by muse, mutect2, varscan2
- YAP1 | c.1105G>A p.G369R (on ENST00000282441 / NM_001130145.3; = p.G315R on NM_006106.5) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1433803164, COSV99176372; called by muse, mutect2, varscan2
- YPEL1 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188706968; called by muse, mutect2, varscan2
- ZBTB7A | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1299968386; called by muse, mutect2, varscan2
- ZC3H13 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.13); catalogued as rs199682940, COSV104387464, COSV54459644; called by muse, mutect2, varscan2
- ZFP1 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770638807, COSV60033043; called by muse, mutect2, varscan2
- ZHX3 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs371613858; called by muse, mutect2
- ZMAT1 | c.123C>T p.D41= | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as rs141888312, COSV65658316; called by muse, mutect2, varscan2
- ZMAT5 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as rs1276287888; called by muse, mutect2, varscan2
- ZNF324 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52180241; called by muse, mutect2, varscan2
- ZNF367 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64547857; called by muse, mutect2, varscan2
- ZNF423 | c.3485G>A p.R1162Q (on ENST00000563137 / NM_001379286.1; = p.R1154Q on NM_015069.4) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs532940886, COSV52188947; called by muse, mutect2, varscan2
- ZNF423 | c.829G>A p.E277K (on ENST00000563137 / NM_001379286.1; = p.E269K on NM_015069.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as rs745876102, COSV52179263; called by muse, mutect2, varscan2
- ZNF425 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as rs147910083; called by muse, mutect2, varscan2
- ZNF521 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs149969134; called by muse, mutect2, varscan2
- ZNF546 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs765037445; called by muse, mutect2, varscan2
- ZNF764 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.613); catalogued as rs772140866; called by muse, varscan2
- ZSCAN1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs148253808; called by muse, mutect2, varscan2
- ZSCAN20 | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763522543; called by muse, mutect2, varscan2
- ANKRD50 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- C1orf116 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCDC8 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC27 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- CENPF | c.4439G>A p.C1480Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CLPSL2 | c.164T>G p.F55C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL4A1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCP1B | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F7 | c.2680C>T p.R894* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- ESM1 | c.261_282del p.N87Kfs*37 | Frame Shift Del (DEL) | VAF 11/128 reads (9%) | called by mutect2, pindel
- ESR1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIVEP3 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HSD17B1 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- JPH2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR2DL4 | c.220G>A p.A74T (on ENST00000396284; = p.A35T on NM_001080770.2) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- KPNB1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MBTPS2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- OTUD4 | c.3265C>T p.R1089* (on ENST00000447906 / NM_001366057.1; = p.R1024* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- PCDH19 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PI4K2A | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- PLA2G7 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- PLAAT5 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLEKHM3 | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRPF8 | c.5707G>A p.G1903R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPL10A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2
- SF3A2 | c.10del p.Q4Sfs*44 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- THSD1 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZNF503 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2
- ABCA3 | c.2067C>T p.D689= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs765175808; called by muse, mutect2
- ADCY5 | c.1599C>T p.H533= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as rs552930549; called by muse, mutect2, varscan2
- ADCY9 | c.1389C>T p.I463= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV53582610; called by muse, mutect2, varscan2
- ARHGEF15 | c.1785C>T p.I595= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs779827070, COSV62724633, COSV62725454; called by muse, mutect2, varscan2
- ATP2C2 | c.1575C>T p.N525= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs577350687, COSV52297070, COSV52302067; called by muse, mutect2, varscan2
- BUB1 | c.1821G>A p.A607= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs772143908, COSV100241428; called by muse, mutect2
- CAMTA1 | c.2682G>A p.P894= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as rs776020744; called by muse, mutect2, varscan2
- CBL | c.711G>A p.S237= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs146662327; called by muse, mutect2, varscan2
- CDCP2 | c.180C>T p.I60= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs150004831; called by muse, mutect2, varscan2
- CDK3 | c.684C>T p.P228= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs141477491; called by muse, mutect2, varscan2
- CFAP61 | c.1656C>T p.R552= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs78795550; called by muse, mutect2, varscan2
- CHIT1 | c.219C>T p.D73= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1330040380, COSV55149024; called by muse, mutect2, varscan2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2, varscan2
- CLEC18B | c.354G>A p.A118= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs779514803, COSV60579116; called by muse, mutect2, varscan2
- CNTN1 | c.2784C>T p.V928= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs758326489; called by muse, mutect2, varscan2
- COL4A1 | c.4833G>A p.A1611= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs771624014, COSV65431424; called by muse, mutect2, varscan2
- CSF2RA | c.741G>A p.S247= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs761160075, COSV100817685, COSV62627212; called by muse, mutect2, varscan2
- CSF3 | c.519C>T p.F173= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs774912212, COSV56641658; ClinVar: benign; called by mutect2, varscan2
- CSMD1 | c.2235C>T p.N745= (on ENST00000520002; = p.N744= on NM_033225.6) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1471534448; called by muse, mutect2, varscan2
- CSMD2 | c.5478C>T p.I1826= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs761883622, COSV53876669; called by muse, mutect2, varscan2
- CYB561 | c.9C>T p.G3= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs768220809; called by muse, varscan2
- DCTN1 | c.2478G>A p.T826= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as rs1473795697; called by muse, mutect2, varscan2
- DCTN1 | c.1527G>A p.T509= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs777762235; called by muse, mutect2, varscan2
- DHPS | c.432G>A p.A144= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs776689877, COSV52951698; called by mutect2, varscan2
- DOCK10 | c.3105C>T p.S1035= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs369199175; called by muse, mutect2, varscan2
- EHD1 | c.1062G>A p.P354= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs144668933; called by muse, mutect2, varscan2
- ELMOD2 | c.423G>A p.T141= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs1041416616, COSV60270867; called by muse, mutect2, varscan2
- EMC1 | c.1788G>A p.S596= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs150315726; called by muse, mutect2, varscan2
- ERCC6L | c.1518C>T p.I506= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs1037136790; called by muse, mutect2, varscan2
- FXR2 | c.783C>T p.T261= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs779325705; called by muse, mutect2, varscan2
- GIT1 | c.2013C>T p.F671= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs745617945, COSV99838480; called by muse, mutect2, varscan2
- GIT1 | c.1488C>T p.G496= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs768836653; called by muse, mutect2, varscan2
- GREB1 | c.5190C>T p.N1730= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs368127534, COSV52180306; called by muse, mutect2, varscan2
- HCN4 | c.2538G>A p.P846= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs372747050; called by muse, mutect2, varscan2
- HLCS | c.1638C>T p.S546= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs536830110, COSV60793644; called by muse, mutect2, varscan2
- HTT | c.1167C>T p.P389= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs759711755; called by muse, mutect2, varscan2
- IGDCC3 | c.1929C>T p.I643= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs759891168, COSV60078987; called by muse, mutect2, varscan2
- IGHV3-16 | c.231G>A p.T77= | Silent (SNP) | VAF 66/69 reads (96%) | catalogued as rs1427833114; called by muse, mutect2, varscan2
- INPP5F | c.591C>T p.D197= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs375176930; called by muse, mutect2, varscan2
- ITGA2 | c.1521C>T p.D507= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs371281604; called by muse, mutect2, varscan2
- ITGA5 | c.1005C>T p.V335= | Silent (SNP) | VAF 43/68 reads (63%) | catalogued as rs1287637256; called by muse, mutect2, varscan2
- JPH3 | c.1923C>T p.D641= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs749538454, COSV52465723; called by muse, mutect2, varscan2
- KCNA5 | c.990G>A p.T330= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1174477337, COSV52904835, COSV99363676; called by muse, mutect2, varscan2
- KCNMA1 | c.3297C>T p.R1099= (on ENST00000286628 / NM_001161352.2; = p.R1041= on NM_002247.4) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs372103668; called by muse, mutect2, varscan2
- KCNT1 | c.894C>T p.Y298= (on ENST00000488444; = p.Y317= on NM_020822.3) | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs747685419; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA1958 | c.1482C>T p.V494= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs773442119; called by muse, mutect2, varscan2
- KIRREL1 | c.285C>T p.D95= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as rs746915018; called by muse, mutect2, varscan2
- KL | c.2730C>T p.C910= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs758010223; called by muse, mutect2, varscan2
- KLHL41 | c.207G>A p.A69= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs373592757; called by muse, varscan2
- KRI1 | c.528C>T p.G176= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs565439115, COSV100469798; called by mutect2, varscan2
- L3MBTL2 | c.1446C>T p.H482= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs764759330; called by muse, mutect2, varscan2
- LRRC8A | c.1146C>T p.Y382= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs776535684; called by muse, mutect2, varscan2
- LTBP4 | c.3900C>T p.C1300= (on ENST00000308370 / NM_001042544.1; = p.C1263= on NM_003573.2) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs778594212; ClinVar: likely benign; called by muse, mutect2, varscan2
- LYST | c.11043C>T p.G3681= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs757560834; called by muse, mutect2, varscan2
- MAN1A1 | c.1713C>T p.A571= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs1227429309; called by muse, mutect2, varscan2
- MAN2B1 | c.2796C>T p.S932= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs1403072896, COSV55474793; called by muse, mutect2, varscan2
- MRGPRX2 | c.99G>A p.P33= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as rs771220636; called by muse, mutect2, varscan2
- MS4A15 | c.15C>T p.P5= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs372949576; called by muse, mutect2, varscan2
- MSRB3 | c.543C>T p.V181= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs370488628; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTMR14 | c.1887C>T p.I629= (on ENST00000296003 / NM_001077525.3; = p.I517= on NM_022485.5) | Silent (SNP) | VAF 23/24 reads (96%) | catalogued as rs777595702; called by muse, mutect2, varscan2
- MUC3A | c.7485G>A p.S2495= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as rs79067082, COSV60210457; called by muse, mutect2, varscan2
- MYL10 | c.459G>A p.T153= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs567400190, COSV56209057; called by muse, mutect2, varscan2
- MYO3B | c.3453C>T p.S1151= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs750438385; called by muse, mutect2, varscan2
- MYO7A | c.2307C>T p.N769= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs782329400, CD136753; called by muse, mutect2, varscan2
- NBPF3 | c.1665C>T p.N555= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs1160087291, COSV59057561; called by muse, mutect2, varscan2
- NCOA6 | c.5592C>T p.L1864= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV100750322; called by muse, mutect2, varscan2
- NECTIN1 | c.1437C>T p.D479= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs141036439; called by mutect2, varscan2
- NOTCH2 | c.1911G>A p.T637= | Silent (SNP) | VAF 11/180 reads (6%) | catalogued as rs369028361; called by muse, mutect2
- NUFIP2 | c.1695C>T p.Y565= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs150088850; called by muse, mutect2, varscan2
- NYX | c.834C>T p.A278= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs766462613; called by muse, mutect2, varscan2
- PCDHGA6 | c.1098C>T p.I366= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as rs868598149; called by muse, mutect2
- PDGFRA | c.2265C>T p.S755= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs149659832, COSV99957457; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIGU | c.1029C>T p.P343= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs776500928; called by muse, varscan2
- PLCL1 | c.516G>A p.T172= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs750066298, COSV70821920; called by muse, mutect2, varscan2
- POLD1 | c.2334C>T p.A778= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1472994995; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPEF1 | c.462G>A p.P154= | Silent (SNP) | VAF 103/231 reads (45%) | catalogued as rs143899775; called by muse, mutect2, varscan2
- PPL | c.5055C>T p.F1685= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs772773621; called by muse, mutect2, varscan2
- PRKDC | c.1131C>T p.N377= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1287171364, COSV58046196; called by mutect2, varscan2
- PTCD1 | c.1623G>A p.A541= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99464024; called by muse, mutect2, varscan2
- PVRIG | c.126G>A p.P42= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs1397982881; called by muse, mutect2, varscan2
- PWWP3A | c.279C>T p.R93= (on ENST00000627377; = p.R92= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs769424395; called by muse, mutect2, varscan2
- RNASEH2A | c.402C>T p.N134= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as rs778120777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF113B | c.33C>T p.A11= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs754829186; called by muse, mutect2, varscan2
- ROBO1 | c.2799G>A p.A933= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as rs374375350; called by muse, mutect2, varscan2
- S1PR4 | c.642C>T p.G214= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as rs760646337; called by muse, mutect2, varscan2
- SALL3 | c.2691C>T p.S897= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs755579014, COSV101609935, COSV73306272; called by muse, mutect2, varscan2
- SCN4A | c.5145C>T p.Y1715= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs768902509; called by muse, mutect2, varscan2
- SEC16A | c.1065C>T p.A355= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs761577334; called by muse, mutect2, varscan2
- SLC25A12 | c.1935G>A p.T645= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs369901246; called by muse, mutect2, varscan2
- SLC25A18 | c.795C>T p.T265= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs556042476, COSV53660170; called by muse, mutect2, varscan2
- SLC25A28 | c.810C>T p.C270= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1193525175, COSV100979652; called by muse, mutect2, varscan2
- SLC45A4 | c.1665C>T p.N555= (on ENST00000517878 / NM_001286646.2; = p.N504= on NM_001080431.2) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1049181128, COSV50140615; called by muse, mutect2, varscan2
- SLC4A2 | c.2253C>T p.G751= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs776758339, COSV99879545; called by muse, mutect2, varscan2
- SLC6A5 | c.2268G>A p.P756= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs373204248; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A9 | c.1881C>T p.Y627= (on ENST00000360584 / NM_201649.4; = p.Y573= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs145370858; called by muse, mutect2, varscan2
- SPG7 | c.1614C>T p.F538= (on ENST00000268704; = p.F545= on NM_003119.4) | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs770394077; called by muse, mutect2, varscan2
- STK11IP | c.1653C>T p.G551= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs773472469; called by muse, mutect2, varscan2
- STON1 | c.1659G>A p.A553= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs370458736, COSV100561493; called by muse, mutect2, varscan2
- SYTL3 | c.1320C>T p.Y440= (on ENST00000611299 / NM_001242394.1; = p.Y372= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs746313196, COSV51916175; called by muse, mutect2, varscan2
- TADA3 | c.420C>T p.I140= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs760618790, COSV55029673; called by muse, mutect2, varscan2
- TAS1R2 | c.885C>T p.G295= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs148401055; called by muse, mutect2
- TECTA | c.2793C>T p.N931= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs750710717; called by muse, mutect2, varscan2
- TLE5 | c.36G>A p.S12= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs1304356681; called by muse, mutect2, varscan2
- TMTC1 | c.2019C>T p.Y673= (on ENST00000539277 / NM_001193451.2; = p.Y565= on NM_175861.3) | Silent (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- TMTC3 | c.1122C>T p.A374= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs376400054; called by muse, mutect2, varscan2
- TNIP2 | c.876G>A p.A292= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs755915638, COSV59569405; called by muse, mutect2, varscan2
- TNNT3 | c.132C>T p.D44= (on ENST00000397301 / NM_001367846.1; = p.D33= on NM_006757.4) | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs752603163, COSV53488587; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNS3 | c.1992G>A p.A664= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as rs374818505; called by muse, mutect2, varscan2
- TNS3 | c.1638C>T p.D546= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs375420968; called by muse, mutect2, varscan2
- TNXB | c.10485C>T p.T3495= (on ENST00000647633; = p.T3248= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1239982151, COSV64478180; called by muse, mutect2, varscan2
- TRPM2 | c.384C>T p.G128= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs143653746; called by muse, mutect2, varscan2
- TTBK1 | c.3201G>A p.S1067= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs376415608; called by muse, mutect2, varscan2
- ULK1 | c.957C>T p.G319= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs756270836; called by muse, mutect2, varscan2
- UNC5C | c.960G>A p.T320= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs760640387, COSV71661177; called by muse, mutect2, varscan2
- VWF | c.3945C>T p.R1315= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs143009893; called by muse, varscan2
- ZCCHC2 | c.2988C>T p.N996= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs780469141, COSV99502318; called by muse, mutect2, varscan2
- ZFHX3 | c.879C>T p.Y293= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs183134469, COSV51720547, COSV51737782; called by muse, mutect2, varscan2
- ZFHX3 | c.390C>T p.A130= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs144573608; called by muse, mutect2, varscan2
- ZNF629 | c.2340C>T p.R780= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs1411967172, COSV52698695; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851224 G>A | 3'Flank (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- FAM193B | c.1275+1120G>A | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as rs763954713; called by muse, varscan2
- HERC2P3 | chr15:20457656 C>T | 5'Flank (SNP) | VAF 7/34 reads (21%) | catalogued as rs761042944; called by muse, mutect2, varscan2
- MFSD4B | c.27+2624G>A | Intron (SNP) | VAF 62/198 reads (31%) | catalogued as rs200995803, COSV64348666; called by muse, mutect2, varscan2
- MIR516A2 | n.21G>A | RNA (SNP) | VAF 36/86 reads (42%) | catalogued as rs754319127; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792083 C>T | 3'Flank (SNP) | VAF 17/33 reads (52%) | catalogued as rs113961788; called by muse, mutect2, varscan2
